Somatic mutation profile of cancer-model specimen HCM-CSHL-0800-C67-85A (3D Organoid, passage 3; aliquot HCM-CSHL-0800-C67-85A-01D-A88G-36), derived from the primary tumor of HCMI case HCM-CSHL-0800-C67, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; Tumor grade: G3.
Specimen HCM-CSHL-0800-C67-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 3.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 079d673e-3bc6-4234-acc6-0d939b547729.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0800-C67-10A (Blood Derived Normal), aliquot HCM-CSHL-0800-C67-10A-01D-A88G-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dcb39d7c-33c7-4132-8a65-a8512751280c

The open-access MAF lists 172 somatic variants for this specimen: 123 protein-altering or splice-affecting, 47 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 104, Silent 47, Frame Shift Del 8, Nonsense Mutation 7, Splice Site 2, Frame Shift Ins 1, Intron 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.1161T>A p.N387K | Missense Mutation (SNP) | VAF 12/322 reads (4%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868651538, COSV62688055, COSV62689041; called by muse, mutect2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 172/177 reads (97%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAM20 | c.1150T>C p.Y384H | Missense Mutation (SNP) | VAF 97/252 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs775126973; called by muse, mutect2, varscan2
- ALKBH5 | c.935C>T p.S312L | Missense Mutation (SNP) | VAF 293/572 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.26); catalogued as rs1277969333; called by muse, varscan2
- AMBRA1 | c.1757G>A p.R586K (on ENST00000458649 / NM_001367468.1; = p.R496K on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 227/466 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs1467832951; called by muse, mutect2, varscan2
- ANKDD1A | c.1204C>T p.Q402* | Nonsense Mutation (SNP) | VAF 27/324 reads (8%) | catalogued as rs929387778; called by muse, mutect2
- ARHGAP9 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 162/307 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs750846549, COSV62724261; called by muse, mutect2, varscan2
- ATP13A4 | c.476C>A p.S159Y | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV55069302; called by muse, mutect2
- B3GNT8 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 171/410 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs762148606, COSV54200237; called by muse, varscan2
- BPTF | c.322G>A p.G108S | Missense Mutation (SNP) | VAF 194/336 reads (58%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.151); catalogued as rs1404235926; called by muse, varscan2
- CCDC168 | c.11695G>A p.E3899K | Missense Mutation (SNP) | VAF 77/350 reads (22%) | SIFT tolerated (0.76); PolyPhen benign (0.104); catalogued as rs1441712597; called by muse, mutect2, varscan2
- CDH10 | c.1515G>A p.Q505= | Splice Region (SNP) | VAF 62/370 reads (17%) | catalogued as COSV100053074; called by muse, mutect2, varscan2
- CREM | c.644C>G p.S215* (on ENST00000429130; = p.S182* on NM_181571.3) | Nonsense Mutation (SNP) | VAF 13/366 reads (4%) | catalogued as COSV100415160; called by muse, mutect2
- CRYBG1 | c.554C>T p.S185F | Missense Mutation (SNP) | VAF 306/629 reads (49%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.01); catalogued as rs751639948; called by muse, mutect2, varscan2
- DCAF12 | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 238/473 reads (50%) | catalogued as COSV63512057; called by muse, varscan2
- DHRS3 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 161/407 reads (40%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV66108434; called by muse, mutect2, varscan2
- DOCK4 | c.2062C>T p.R688W | Missense Mutation (SNP) | VAF 78/235 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.044); catalogued as COSV70235905; called by muse, mutect2, varscan2
- EFNB2 | c.895G>A p.V299I | Missense Mutation (SNP) | VAF 140/457 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.079); catalogued as rs770833245, COSV55364263; called by muse, mutect2, varscan2
- ELF3 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 157/416 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs868080326, COSV62838832; called by muse, mutect2, varscan2
- ENDOU | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 154/441 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.545); catalogued as rs1029433690; called by muse, mutect2, varscan2
- GDF6 | c.521C>A p.S174* | Nonsense Mutation (SNP) | VAF 156/614 reads (25%) | catalogued as COSV54625541; called by muse, mutect2, varscan2
- H1-4 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 328/653 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1276316143, COSV56803254, COSV56803481; called by muse, mutect2, varscan2
- HLA-DQB2 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 361/1122 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as rs540615740, COSV68614356; called by muse, varscan2
- HPSE2 | c.880C>T p.R294W | Missense Mutation (SNP) | VAF 254/255 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370784296, COSV65185652; called by muse, mutect2, varscan2
- HRG | c.106G>C p.D36H | Missense Mutation (SNP) | VAF 162/475 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs902340759; called by muse, mutect2, varscan2
- ITPA | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 211/440 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0.046); catalogued as rs757955055; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIN | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 186/289 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as rs61752337, COSV65431526; called by muse, mutect2, varscan2
- OR5L1 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 152/751 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1363294712, COSV61732870, COSV61733662; called by muse, mutect2, varscan2
- PDE12 | c.34C>T p.R12W | Missense Mutation (SNP) | VAF 14/448 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.333); catalogued as rs1044804935; called by muse, mutect2
- PLEKHF1 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 14/386 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.283); catalogued as COSV101460779, COSV71410333; called by muse, mutect2
- PPP1R13B | c.2032A>G p.I678V | Missense Mutation (SNP) | VAF 392/401 reads (98%) | SIFT tolerated (0.55); PolyPhen benign (0.031); catalogued as rs748717066; called by muse, mutect2, varscan2
- PXDNL | c.3068G>A p.G1023E | Missense Mutation (SNP) | VAF 158/513 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1000906534; called by muse, mutect2, varscan2
- RTP5 | c.127G>A p.G43S | Missense Mutation (SNP) | VAF 550/571 reads (96%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as rs774009607; called by muse, mutect2, varscan2
- SLC35F3 | c.42G>T p.K14N | Missense Mutation (SNP) | VAF 107/357 reads (30%) | SIFT tolerated, low confidence (0.31); PolyPhen probably damaging (0.978); catalogued as COSV64026598; called by muse, mutect2, varscan2
- SLCO1C1 | c.49G>T p.V17L | Missense Mutation (SNP) | VAF 101/376 reads (27%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs771985338; called by muse, mutect2, varscan2
- SPTBN5 | c.2699G>A p.G900D | Missense Mutation (SNP) | VAF 278/474 reads (59%) | SIFT tolerated (0.64); PolyPhen benign (0.065); catalogued as COSV58026205; called by muse, mutect2, varscan2
- STON1 | c.1319C>G p.T440S | Missense Mutation (SNP) | VAF 201/427 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs1193202412; called by muse, mutect2, varscan2
- TCOF1 | c.1040C>T p.S347F (on ENST00000377797 / NM_001135243.1; = p.S270F on NM_000356.4) | Missense Mutation (SNP) | VAF 12/309 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1434625736; called by muse, mutect2
- TENM3 | c.7336G>A p.D2446N | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.407); catalogued as rs1423201191, COSV101305079; called by muse, mutect2
- TMCO4 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 154/309 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs564460987; called by muse, mutect2, varscan2
- TMEM130 | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 90/390 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs147591838; called by muse, mutect2, varscan2
- TMEM131L | c.1061-2A>T p.X354_splice | Splice Site (SNP) | VAF 14/206 reads (7%) | catalogued as COSV53645517; called by muse, mutect2
- TMPPE | c.532G>A p.V178M | Missense Mutation (SNP) | VAF 16/404 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as rs1187389735; called by muse, mutect2
- TNNT2 | c.775G>A p.D259N (on ENST00000236918; = p.D256N on NM_000364.4) | Missense Mutation (SNP) | VAF 206/370 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as rs141805127; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- TSNAXIP1 | c.1335C>G p.I445M | Missense Mutation (SNP) | VAF 64/423 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.237); catalogued as COSV54652606; called by muse, mutect2, varscan2
- USPL1 | c.1790C>T p.S597L | Missense Mutation (SNP) | VAF 44/279 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.258); catalogued as rs1372689176; called by muse, mutect2, varscan2
- VPS16 | c.1574G>A p.R525Q | Missense Mutation (SNP) | VAF 84/550 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.265); catalogued as rs143701351; called by muse, mutect2, varscan2
- VWA8 | c.4493G>T p.G1498V | Missense Mutation (SNP) | VAF 105/251 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.327); catalogued as COSV64999621; called by muse, mutect2, varscan2
- ZBTB18 | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 128/410 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs765153679; called by muse, varscan2
- ZNF212 | c.1003C>G p.L335V | Missense Mutation (SNP) | VAF 262/554 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.192); catalogued as COSV60026086; called by muse, mutect2, varscan2
- ZNF479 | c.122A>G p.Y41C | Missense Mutation (SNP) | VAF 127/380 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753095929; called by muse, mutect2, varscan2
- AC005324.2 | c.695A>G p.N232S | Missense Mutation (SNP) | VAF 20/730 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); called by muse, mutect2
- AC100868.1 | c.672G>T p.E224D | Missense Mutation (SNP) | VAF 39/578 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.108); called by muse, mutect2
- ADGRV1 | c.16327C>G p.Q5443E | Missense Mutation (SNP) | VAF 61/212 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANKS1A | c.1435A>T p.S479C | Missense Mutation (SNP) | VAF 239/485 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- APOB | c.4441G>T p.V1481F | Missense Mutation (SNP) | VAF 213/463 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- ARID4A | c.3517C>G p.Q1173E | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- ATF7IP | c.1260T>G p.S420R | Missense Mutation (SNP) | VAF 130/197 reads (66%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CADPS | c.2317G>A p.V773I | Missense Mutation (SNP) | VAF 181/214 reads (85%) | SIFT tolerated (0.17); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- CBX2 | c.1175C>G p.T392S | Missense Mutation (SNP) | VAF 328/367 reads (89%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDC73 | c.925A>G p.I309V | Missense Mutation (SNP) | VAF 14/283 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- CFAP54 | c.3622A>G p.I1208V | Missense Mutation (SNP) | VAF 122/221 reads (55%) | SIFT tolerated (0.5); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CLCNKB | c.1021C>T p.P341S | Missense Mutation (SNP) | VAF 139/386 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLK4 | c.290A>T p.Y97F | Missense Mutation (SNP) | VAF 204/204 reads (100%) | SIFT tolerated (0.24); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- CSMD1 | c.5991C>A p.N1997K (on ENST00000520002; = p.N1996K on NM_033225.6) | Missense Mutation (SNP) | VAF 110/118 reads (93%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, varscan2
- CTNNA2 | c.254T>C p.L85P | Missense Mutation (SNP) | VAF 193/236 reads (82%) | SIFT deleterious (0.02); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- CUL5 | c.484C>G p.L162V | Missense Mutation (SNP) | VAF 177/450 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- DCAF4L2 | c.757C>A p.L253M | Missense Mutation (SNP) | VAF 24/610 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); called by muse, mutect2
- DHX9 | c.3763del p.A1255Pfs*63 | Frame Shift Del (DEL) | VAF 190/406 reads (47%) | called by mutect2, pindel, varscan2
- DNAH8 | c.11305G>C p.D3769H | Missense Mutation (SNP) | VAF 121/315 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- DPP10 | c.1532-1G>A p.X511_splice | Splice Site (SNP) | VAF 138/145 reads (95%) | called by muse, mutect2, varscan2
- EIF4ENIF1 | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 11/342 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ENO4 | c.807G>T p.Q269H (on ENST00000622726; = p.Q268H on NM_001242699.2) | Missense Mutation (SNP) | VAF 82/189 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- EPHA2 | c.2470dup p.H824Pfs*9 | Frame Shift Ins (INS) | VAF 106/294 reads (36%) | called by mutect2, pindel, varscan2
- EPHA2 | c.129del p.W43Cfs*12 | Frame Shift Del (DEL) | VAF 181/376 reads (48%) | called by mutect2, pindel, varscan2
- ETFDH | c.1604C>T p.A535V | Missense Mutation (SNP) | VAF 31/256 reads (12%) | SIFT tolerated (0.91); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- FAM89B | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 422/863 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FOCAD | c.3460A>T p.S1154C | Missense Mutation (SNP) | VAF 219/464 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- GOLGA6L2 | c.1054G>T p.E352* | Nonsense Mutation (SNP) | VAF 34/1160 reads (3%) | called by muse, mutect2
- GPLD1 | c.2330C>T p.S777L | Missense Mutation (SNP) | VAF 167/522 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- H4C9 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 120/692 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- HECTD1 | c.5852A>G p.Y1951C | Missense Mutation (SNP) | VAF 126/129 reads (98%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- HELB | c.2828G>T p.R943I | Missense Mutation (SNP) | VAF 289/466 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HERC2 | c.11905G>A p.E3969K | Missense Mutation (SNP) | VAF 264/912 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- IFFO1 | c.205G>C p.D69H | Missense Mutation (SNP) | VAF 187/691 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- KCNK2 | c.208G>T p.V70F (on ENST00000444842 / NM_001017425.3; = p.V55F on NM_014217.4) | Missense Mutation (SNP) | VAF 157/297 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- KDM6A | c.3706_3713del p.N1236Lfs*12 | Frame Shift Del (DEL) | VAF 172/188 reads (91%) | called by mutect2, pindel, varscan2
- LAMB3 | c.2895G>C p.E965D | Missense Mutation (SNP) | VAF 174/453 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- LILRA5 | c.641G>C p.C214S | Missense Mutation (SNP) | VAF 73/426 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAPRE1 | c.535G>T p.V179L | Missense Mutation (SNP) | VAF 78/582 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MARCKS | c.782_786del p.P261Qfs*79 | Frame Shift Del (DEL) | VAF 109/552 reads (20%) | called by mutect2, pindel, varscan2
- MCC | c.1783del p.I595Sfs*31 | Frame Shift Del (DEL) | VAF 80/228 reads (35%) | called by mutect2, pindel, varscan2
- MED12 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 247/247 reads (100%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MTO1 | c.1890T>A p.D630E (on ENST00000370300 / NM_133645.3; = p.D605E on NM_012123.4) | Missense Mutation (SNP) | VAF 183/446 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MYRIP | c.827G>T p.G276V | Missense Mutation (SNP) | VAF 23/380 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.475); called by muse, mutect2
- NCOR2 | c.3960_3964del p.R1320Sfs*91 | Frame Shift Del (DEL) | VAF 156/390 reads (40%) | called by mutect2, pindel, varscan2
- NLRP2 | c.2731A>C p.S911R | Missense Mutation (SNP) | VAF 153/462 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- NPFFR1 | c.912C>G p.H304Q | Missense Mutation (SNP) | VAF 459/474 reads (97%) | SIFT tolerated (0.96); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- OR6N2 | c.536G>C p.C179S | Missense Mutation (SNP) | VAF 111/382 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCNX2 | c.5189A>G p.E1730G | Missense Mutation (SNP) | VAF 116/347 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIK3C2G | c.1019A>G p.E340G | Missense Mutation (SNP) | VAF 86/232 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PIK3CA | c.1120C>G p.Q374E | Missense Mutation (SNP) | VAF 71/219 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PKD2 | c.139T>C p.C47R | Missense Mutation (SNP) | VAF 46/374 reads (12%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, varscan2
- PLEC | c.7901_7902del p.S2634* (on ENST00000322810 / NM_201380.4; = p.S2524* on NM_000445.5) | Frame Shift Del (DEL) | VAF 114/522 reads (22%) | called by pindel, varscan2
- PLEKHB2 | c.871G>A p.V291M | Missense Mutation (SNP) | VAF 28/676 reads (4%) | PolyPhen benign (0); called by muse, mutect2
- PNPLA3 | c.209C>G p.S70* | Nonsense Mutation (SNP) | VAF 80/272 reads (29%) | called by muse, mutect2, varscan2
- PPFIBP1 | c.1572del p.F525Lfs*20 (on ENST00000318304 / NM_177444.3; = p.F508Lfs*20 on NM_003622.4) | Frame Shift Del (DEL) | VAF 132/490 reads (27%) | called by mutect2, pindel, varscan2
- PREX1 | c.892C>T p.L298F | Missense Mutation (SNP) | VAF 213/603 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAB3GAP2 | c.2728C>G p.Q910E | Missense Mutation (SNP) | VAF 132/289 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RAB7A | c.137T>A p.L46Q | Missense Mutation (SNP) | VAF 97/295 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- SHB | c.392C>A p.S131* | Nonsense Mutation (SNP) | VAF 206/752 reads (27%) | called by muse, mutect2, varscan2
- SLFN5 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 211/429 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLITRK3 | c.351G>T p.Q117H | Missense Mutation (SNP) | VAF 81/244 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOD3 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 200/274 reads (73%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- ST6GALNAC3 | c.632C>A p.S211Y | Missense Mutation (SNP) | VAF 97/251 reads (39%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAAR2 | c.523G>T p.A175S (on ENST00000367931 / NM_001033080.1; = p.A130S on NM_014626.3) | Missense Mutation (SNP) | VAF 95/361 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- TBC1D32 | c.758A>G p.Y253C | Missense Mutation (SNP) | VAF 59/298 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TENM3 | c.6805G>A p.E2269K | Missense Mutation (SNP) | VAF 59/282 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- TTN | c.85159G>C p.A28387P (on ENST00000591111; = p.A20963P on NM_003319.4) | Missense Mutation (SNP) | VAF 340/352 reads (97%) | PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- TTN | c.41206C>A p.Q13736K (on ENST00000591111; = p.Q6312K on NM_003319.4) | Missense Mutation (SNP) | VAF 16/462 reads (3%) | PolyPhen benign (0.116); called by muse, mutect2
- UGCG | c.982A>G p.I328V | Missense Mutation (SNP) | VAF 292/302 reads (97%) | SIFT tolerated (0.15); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- XKR4 | c.1561G>A p.G521R | Missense Mutation (SNP) | VAF 94/308 reads (31%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ZNF613 | c.664C>T p.H222Y (on ENST00000293471 / NM_001031721.4; = p.H186Y on NM_024840.4) | Missense Mutation (SNP) | VAF 75/495 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APLP2 | c.543A>G p.L181= | Silent (SNP) | VAF 184/354 reads (52%) | catalogued as rs749689111; called by muse, mutect2, varscan2
- ARHGAP25 | c.1410C>T p.F470= (on ENST00000409202 / NM_001007231.3; = p.F462= on NM_014882.3) | Silent (SNP) | VAF 304/331 reads (92%) | catalogued as rs1449913073, COSV54909752; called by muse, mutect2, varscan2
- ARHGAP44 | c.759C>T p.F253= | Silent (SNP) | VAF 75/557 reads (13%) | catalogued as rs369346611; called by muse, mutect2, varscan2
- ARSB | c.582T>C p.L194= | Silent (SNP) | VAF 240/241 reads (100%) | called by muse, mutect2, varscan2
- ATL2 | c.1240C>T p.L414= | Silent (SNP) | VAF 107/474 reads (23%) | called by muse, mutect2, varscan2
- BRINP1 | c.594C>T p.R198= | Silent (SNP) | VAF 214/219 reads (98%) | called by muse, mutect2, varscan2
- C2CD2L | c.978G>A p.A326= | Silent (SNP) | VAF 184/373 reads (49%) | called by muse, mutect2, varscan2
- CCDC14 | c.1974A>G p.T658= (on ENST00000488653; = p.T610= on NM_022757.5) | Silent (SNP) | VAF 87/274 reads (32%) | catalogued as COSV59946829; called by muse, mutect2, varscan2
- CDS2 | c.12G>A p.L4= | Silent (SNP) | VAF 233/506 reads (46%) | called by muse, mutect2, varscan2
- CFAP61 | c.330C>T p.A110= | Silent (SNP) | VAF 93/459 reads (20%) | catalogued as rs143210107; called by muse, mutect2, varscan2
- DHRS3 | c.177G>A p.A59= | Silent (SNP) | VAF 162/408 reads (40%) | catalogued as rs775881306; called by muse, mutect2, varscan2
- DNM3 | c.561G>A p.L187= | Silent (SNP) | VAF 103/264 reads (39%) | called by muse, mutect2, varscan2
- ETHE1 | c.24C>T p.V8= | Silent (SNP) | VAF 182/423 reads (43%) | called by muse, mutect2
- FILIP1 | c.354G>A p.A118= | Silent (SNP) | VAF 248/530 reads (47%) | catalogued as rs773253915; called by muse, mutect2, varscan2
- HES7 | c.183C>T p.F61= | Silent (SNP) | VAF 248/538 reads (46%) | catalogued as rs1348583817; called by muse, varscan2
- HIC1 | c.2175G>C p.R725= (on ENST00000322941 / NM_001098202.1; = p.R706= on NM_006497.4) | Silent (SNP) | VAF 14/402 reads (3%) | called by muse, mutect2
- HMCN2 | c.15096C>A p.L5032= | Silent (SNP) | VAF 579/579 reads (100%) | called by muse, mutect2, varscan2
- HOXD9 | c.954G>T p.V318= | Silent (SNP) | VAF 311/323 reads (96%) | called by muse, mutect2, varscan2
- KCNS2 | c.987A>C p.V329= | Silent (SNP) | VAF 357/501 reads (71%) | called by muse, varscan2
- KPNA2 | c.1185G>A p.K395= | Silent (SNP) | VAF 111/284 reads (39%) | catalogued as rs782720399; called by muse, mutect2, varscan2
- NAGLU | c.354G>A p.P118= | Silent (SNP) | VAF 294/631 reads (47%) | catalogued as rs745433070; called by muse, mutect2, varscan2
- NALCN | c.1155T>A p.V385= | Silent (SNP) | VAF 219/345 reads (63%) | called by muse, mutect2, varscan2
- OR9Q1 | c.246G>A p.L82= | Silent (SNP) | VAF 103/608 reads (17%) | called by muse, mutect2, varscan2
- PPARA | c.24C>T p.L8= | Silent (SNP) | VAF 49/293 reads (17%) | called by muse, mutect2, varscan2
- PPEF2 | c.207C>G p.L69= | Silent (SNP) | VAF 55/283 reads (19%) | called by muse, mutect2, varscan2
- PPP1R3G | c.780C>T p.F260= | Silent (SNP) | VAF 264/710 reads (37%) | called by muse, mutect2, varscan2
- PPP1R3G | c.781C>T p.L261= | Silent (SNP) | VAF 262/703 reads (37%) | called by muse, mutect2, varscan2
- PTCHD1 | c.270C>T p.P90= | Silent (SNP) | VAF 16/572 reads (3%) | catalogued as COSV65059788; called by muse, mutect2
- RANBP3L | c.1059C>G p.L353= | Silent (SNP) | VAF 83/728 reads (11%) | called by muse, mutect2, varscan2
- RAP1GAP2 | c.2130G>A p.P710= | Silent (SNP) | VAF 160/170 reads (94%) | catalogued as rs748592156, COSV99621854; called by muse, mutect2, varscan2
- RIN1 | c.1086G>A p.R362= | Silent (SNP) | VAF 42/963 reads (4%) | called by muse, mutect2
- RNF223 | c.420C>G p.T140= | Silent (SNP) | VAF 247/635 reads (39%) | called by muse, mutect2, varscan2
- ROBO4 | c.798C>T p.L266= | Silent (SNP) | VAF 177/367 reads (48%) | called by muse, mutect2, varscan2
- RRAS | c.627G>A p.K209= | Silent (SNP) | VAF 202/350 reads (58%) | called by muse, varscan2
- RUVBL2 | c.726G>T p.V242= | Silent (SNP) | VAF 138/446 reads (31%) | called by muse, mutect2, varscan2
- SAMD10 | c.537C>T p.L179= | Silent (SNP) | VAF 375/1264 reads (30%) | called by muse, mutect2, varscan2
- SLC4A9 | c.2547G>A p.V849= (on ENST00000507527 / NM_001258428.2; = p.V825= on NM_031467.3) | Silent (SNP) | VAF 70/199 reads (35%) | catalogued as rs959266774; called by muse, mutect2, varscan2
- SLC6A5 | c.138G>A p.P46= | Silent (SNP) | VAF 141/434 reads (32%) | called by muse, mutect2, varscan2
- SNX21 | c.183C>T p.L61= | Silent (SNP) | VAF 188/1193 reads (16%) | called by muse, mutect2, varscan2
- TDRD12 | c.2931C>A p.V977= (on ENST00000444215; = p.V982= on NM_001366102.1) | Silent (SNP) | VAF 176/298 reads (59%) | called by muse, varscan2
- TDRD12 | c.2967C>T p.F989= (on ENST00000444215; = p.F994= on NM_001366102.1) | Silent (SNP) | VAF 110/301 reads (37%) | called by muse, varscan2
- THBS3 | c.414C>T p.A138= | Silent (SNP) | VAF 46/688 reads (7%) | called by muse, mutect2
- TULP4 | c.2988C>T p.L996= | Silent (SNP) | VAF 24/799 reads (3%) | catalogued as rs1436184540; called by muse, mutect2
- WDR27 | c.1506C>T p.T502= | Silent (SNP) | VAF 150/258 reads (58%) | catalogued as rs1346065898; called by muse, mutect2, varscan2
- WNT6 | c.246C>T p.F82= | Silent (SNP) | VAF 613/651 reads (94%) | called by muse, mutect2, varscan2
- ZNF106 | c.5022C>T p.V1674= | Silent (SNP) | VAF 126/397 reads (32%) | catalogued as rs765768530, COSV55514523; called by muse, mutect2, varscan2
- ZNF384 | c.1062C>T p.F354= | Silent (SNP) | VAF 197/323 reads (61%) | called by muse, mutect2, varscan2
- RAB11FIP5 | c.1569-4739C>G | Intron (SNP) | VAF 10/344 reads (3%) | called by muse, mutect2
- TIGIT | chr3:114293890 G>A | 5'Flank (SNP) | VAF 85/376 reads (23%) | catalogued as rs1173238936; called by muse, mutect2, varscan2
